Somatic mutation profile of tumor specimen TARGET-20-PASELK-03A (aliquot TARGET-20-PASELK-03A-01D) from TARGET case TARGET-20-PASELK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.3 years (6,680 days).
Specimen TARGET-20-PASELK-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e41c1c90-5e09-4641-a187-efa77529a910.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASELK-14A (Bone Marrow Normal), aliquot TARGET-20-PASELK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2ba8759-f296-491e-8513-05b440592ec2

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 362/397 reads (91%) | hotspot (GDC flag); catalogued as rs878853865, CM000780, COSV62194747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.759_771+5delinsTC p.X253_splice | Splice Site (DEL) | VAF 72/201 reads (36%) | called by pindel, varscan2*
